Somatic mutation profile of tumor specimen TARGET-40-PASSLM-01A (aliquot TARGET-40-PASSLM-01A-01D) from TARGET case TARGET-40-PASSLM, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of upper limb, scapula and associated joints; Age at diagnosis: 9.7 years (3,538 days).
Specimen TARGET-40-PASSLM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b1d8d04-4caf-4f54-8179-9ebcd5dad22b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PASSLM-10A (Blood Derived Normal), aliquot TARGET-40-PASSLM-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/603f8e09-3dc6-4eaa-993e-561e59408209

The open-access MAF lists 34 somatic variants for this specimen: 18 protein-altering or splice-affecting, 7 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 7, Intron 4, RNA 3, Nonsense Mutation 2, 3'Flank 1, 3'UTR 1, Splice Site 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.782+1G>A p.X261_splice | Splice Site (SNP) | VAF 45/48 reads (94%) | hotspot (GDC flag); catalogued as rs1555525429, COSV52665287, COSV52673806, COSV52698978; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FAM91A1 | c.1253A>C p.D418A | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201587994; called by mutect2, varscan2
- GPC5 | c.84G>T p.Q28H | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as COSV65601336; called by muse, mutect2, varscan2
- GRIN2A | c.4126C>T p.R1376C | Missense Mutation (SNP) | VAF 61/107 reads (57%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.761); catalogued as rs1426934537, COSV58023359, COSV58024387; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HAUS8 | c.929+7C>T | Splice Region (SNP) | VAF 90/138 reads (65%) | catalogued as rs547886350, COSV53725610; called by muse, mutect2, varscan2
- IL36G | c.20A>G p.D7G | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs769970410; called by muse, mutect2, varscan2
- KCNK10 | c.1043C>T p.T348M | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.932); catalogued as rs1444705240, COSV100067793; called by muse, mutect2, varscan2
- MAP3K13 | c.563G>T p.R188L | Missense Mutation (SNP) | VAF 42/173 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV53984208; called by muse, mutect2, varscan2
- PAQR9 | c.838C>G p.R280G | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.803); catalogued as rs779378995, COSV61418503; called by muse, mutect2, varscan2
- SAMD3 | c.457C>A p.P153T | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as COSV60776508; called by muse, mutect2
- ANO3 | c.2440G>A p.G814R | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATRX | c.2868dup p.V957Sfs*7 | Frame Shift Ins (INS) | VAF 255/382 reads (67%) | called by mutect2, pindel, varscan2
- ENAM | c.2585A>G p.E862G | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- KIF13B | c.1660G>T p.E554* | Nonsense Mutation (SNP) | VAF 63/287 reads (22%) | called by muse, mutect2, varscan2
- NEURL1 | c.1373C>G p.S458* | Nonsense Mutation (SNP) | VAF 37/95 reads (39%) | called by muse, mutect2, varscan2
- PGAP6 | c.1563C>G p.C521W | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RPTOR | c.2652C>A p.S884R | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SGIP1 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 73/193 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ADAM20 | c.1719C>A p.P573= | Silent (SNP) | VAF 45/271 reads (17%) | called by muse, mutect2, varscan2
- ADCY10 | c.4056C>T p.Y1352= | Silent (SNP) | VAF 36/142 reads (25%) | catalogued as rs779830099; called by muse, varscan2
- CACNA2D4 | c.897C>T p.S299= | Silent (SNP) | VAF 147/331 reads (44%) | catalogued as rs187962821; called by muse, mutect2, varscan2
- DISP3 | c.2280C>T p.F760= | Silent (SNP) | VAF 8/44 reads (18%) | called by muse, mutect2, varscan2
- DNAJC16 | c.1068A>T p.R356= | Silent (SNP) | VAF 36/185 reads (19%) | called by muse, mutect2, varscan2
- MYH6 | c.5142G>C p.R1714= | Silent (SNP) | VAF 33/122 reads (27%) | catalogued as rs755986916; called by muse, mutect2, varscan2
- UGT2A1 | c.939C>T p.N313= | Silent (SNP) | VAF 40/67 reads (60%) | called by muse, mutect2, varscan2
- AC008687.1 | c.-27-1962T>G | Intron (SNP) | VAF 6/50 reads (12%) | catalogued as rs905998588; called by mutect2, varscan2
- AC114324.1 | n.2859C>G | RNA (SNP) | VAF 7/73 reads (10%) | catalogued as rs1248922218; called by muse, mutect2
- ALMS1P1 | chr2:73701255 G>C | 3'Flank (SNP) | VAF 33/184 reads (18%) | called by muse, mutect2
- HNRNPA3 | c.739+32C>G | Intron (SNP) | VAF 6/144 reads (4%) | called by muse, mutect2
- MMP26 | c.-145+93009T>C | Intron (SNP) | VAF 127/218 reads (58%) | called by muse, mutect2, varscan2
- MRM3 | c.*35C>T | 3'UTR (SNP) | VAF 15/40 reads (38%) | called by muse, mutect2, varscan2
- PCNX2 | c.5329-75A>T | Intron (SNP) | VAF 6/16 reads (38%) | called by muse, varscan2
- SSPOP | n.9594C>T | RNA (SNP) | VAF 5/11 reads (45%) | called by muse, mutect2, varscan2
- ZNF720P1 | n.974T>A | RNA (SNP) | VAF 36/143 reads (25%) | called by muse, mutect2, varscan2
